Gene-level copy-number profile of tumor specimen ALCH-B3DL-TTP1-A from ALCHEMIST case ALCH-B3DL, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 67.0 years (24,481 days).
Specimen ALCH-B3DL-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 08769bb6-c202-417b-8b0e-c52120f6d503.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B3DL-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,227 have no estimate.
https://portal.gdc.cancer.gov/files/ef3c1925-dd2f-45de-8421-ed0e62bd40e4

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 62; copy number 1: 1,408; copy number 2: 56,496; copy number 3: 398; copy number 4: 26; copy number 8: 2; copy number 11: 2; copy number 14: 1; copy number 16: 1.

Homozygous deletions (total copy number 0; autosomes only): 62 genes in 14 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:219,482,073–219,516,877, 5 genes (within-gene range 0–2): ASIC4-AS1, AC053503.6, SPEGNB, AC053503.4, GMPPA.
- chr3:126,524,155–126,558,965, 2 genes: CHST13, C3orf22.
- chr9:131,009,174–131,094,473, 2 genes (within-gene range 0–1): LAMC3, AL583807.1.
- chr10:86,970,237–86,970,826, 1 gene (within-gene range 0–2): AL136982.7.
- chr11:77,066,961–77,215,241, 3 genes: CAPN5, OMP, MYO7A.
- chr15:25,184,306–25,232,468, 27 genes (within-gene range 0–2): SNORD115-8, SNORD115-9, SNORD115-10, SNORD115-11, SNORD115-12, SNORD115-13, SNORD115-14, SNORD115-15, SNORD115-16, SNORD115-17, SNORD115-18, SNORD115-19, SNORD115-20, SNORD115-21, SNORD115-22, SNORD115-23, SNORD115-24, SNORD115-25, SNORD115-26, SNORD115-27, SNORD115-28, SNORD115-29, SNORD115-30, SNORD115-31, SNORD115-32, SNORD115-33, SNORD115-34.
- chr16:81,100,875–81,220,370, 3 genes (within-gene range 0–1): PKD1L2, RNU6-1191P, AC092718.9.
- chr17:2,712,309–2,749,504, 5 genes: AC005696.1, AC005696.4, CCDC92B, MIR1253, hsa-mir-1253.
- chr17:3,662,895–3,696,240, 5 genes: TAX1BP3, P2RX5-TAX1BP3, AC132942.1, EMC6, P2RX5.
- chr17:3,977,103–3,981,899, 1 gene: LINC01975.
- chr18:37,273,706–37,276,572, 1 gene (within-gene range 0–2): AC090386.1.
- chr19:1,321,225–1,322,846, 1 gene (within-gene range 0–2): AC005330.1.
- chr19:9,126,012–9,126,950, 1 gene: OR7G3.
- chr22:19,124,309–19,150,292, 5 genes (within-gene range 0–2): AC004471.2, TSSK1A, ESS2, TSSK2, GSC2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 6 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr19:1,228,287–1,238,027, 1 gene, copy number 16 (within-gene range 3–16): CBARP.
- chr21:44,107,373–44,210,114, 5 genes, copy number 8–14 (within-gene range 2–14): PWP2, GATD3A, LINC01678, AP001056.2, AP001056.1.

Autosomal genes at a single copy (total copy number 1): 1,400. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
